Somatic mutation profile of tumor specimen TCGA-KK-A8IL-01A (aliquot TCGA-KK-A8IL-01A-11D-A364-08) from TCGA case TCGA-KK-A8IL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.3 years (23,849 days).
Specimen TCGA-KK-A8IL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55281448-b76d-42e3-97d3-c7cb283ffd7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IL-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IL-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1229f6f5-ee84-47d8-b6e9-a3f4eec03ef5

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 18, Silent 13, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTBL2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.895); catalogued as rs1279147056, COSV101379336; called by muse, mutect2, varscan2
- CA2 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs948412711, COSV53406876; called by muse, mutect2, varscan2
- CCNB1IP1 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100738577; called by muse, mutect2, varscan2
- CUBN | c.7925G>A p.G2642E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100912714; called by muse, mutect2, varscan2
- GRID1 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.712); catalogued as rs368060520; called by muse, mutect2, varscan2
- KCNH8 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100109882; called by muse, mutect2, varscan2
- KIF16B | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100733786; called by muse, mutect2, varscan2
- MXRA5 | c.6889C>T p.R2297C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777337988, COSV54245677; called by muse, mutect2, varscan2
- NALCN | c.1003A>T p.M335L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as COSV99215296; called by muse, mutect2, varscan2
- NPHP1 | c.1754G>A p.R585Q (on ENST00000393272 / NM_207181.4; = p.R586Q on NM_000272.5) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs534052463, CM163852, COSV100338101; called by muse, mutect2
- PIH1D1 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99221110; called by muse, mutect2, varscan2
- PLCB4 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99595522; called by muse, mutect2, varscan2
- PNRC1 | c.602A>G p.H201R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV60140582; called by muse, mutect2, varscan2
- PYHIN1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs373907087; called by muse, mutect2, varscan2
- RIMBP2 | c.2741T>C p.I914T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99899540; called by muse, mutect2
- SLITRK3 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs754409997, COSV53852080; called by muse, mutect2, varscan2
- SNRPA1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs369821067; called by muse, mutect2, varscan2
- ZNF804B | c.1688A>C p.K563T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100301552, COSV60822838; called by muse, mutect2, varscan2
- KMT2C | c.13457_13469del p.T4486Kfs*27 | Frame Shift Del (DEL) | VAF 34/131 reads (26%) | called by mutect2, pindel, varscan2
- ACCS | c.321A>G p.K107= | Silent (SNP) | VAF 5/105 reads (5%) | catalogued as COSV99772827; called by muse, mutect2
- CDK5 | c.510G>A p.P170= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs754127997, COSV52524936, COSV99876761; called by muse, mutect2, varscan2
- DIP2A | c.2047C>T p.L683= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100595802; called by muse, mutect2
- HMCN1 | c.10245C>A p.A3415= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99629544; called by muse, mutect2, varscan2
- KIF16B | c.1134T>C p.A378= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as COSV100734315; called by muse, mutect2, varscan2
- KRT78 | c.189G>T p.G63= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs766223496, COSV100467329, COSV58850711; called by muse, mutect2, varscan2
- MCM10 | c.2217A>G p.S739= (on ENST00000484800 / NM_182751.3; = p.S738= on NM_018518.5) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV101098149; called by muse, mutect2, varscan2
- NCKAP5 | c.4920T>C p.A1640= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100492192; called by muse, varscan2
- PPP1R3A | c.1806T>C p.H602= | Silent (SNP) | VAF 6/135 reads (4%) | catalogued as rs1405020681, COSV99492982; called by muse, mutect2
- RTN4RL1 | c.429C>T p.G143= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs545335258, COSV100486571; called by muse, mutect2, varscan2
- SEPTIN2 | c.990C>T p.R330= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100764940; called by muse, mutect2
- SH3TC1 | c.1392G>A p.A464= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs752924907, COSV99794857; called by muse, mutect2, varscan2
- SMOC1 | c.1131C>T p.N377= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs773345519, COSV100734595; called by muse, mutect2, varscan2
